Somatic mutation profile of tumor specimen C3L-02551-01 (aliquot CPT0161510006) from CPTAC case C3L-02551, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 50.8 years (18,567 days).
Specimen C3L-02551-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 940520e5-6051-4cfa-b0a4-672e767f53bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02551-31 (Blood Derived Normal), aliquot CPT0162510002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b64067bc-1690-4541-85d9-b2ee6bfd199c

The open-access MAF lists 362 somatic variants for this specimen: 232 protein-altering or splice-affecting, 74 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 171, Silent 74, Frame Shift Del 30, Intron 29, Frame Shift Ins 10, 3'UTR 9, 5'UTR 8, Nonsense Mutation 7, Splice Site 6, In Frame Del 5, RNA 5, 5'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC42 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as rs1553196096; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 61/436 reads (14%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- VHL | c.388G>C p.V130L | Missense Mutation (SNP) | VAF 63/404 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs104893830, CM031394, CM126148, CM961427, COSV56543368, COSV56544519, COSV56551325, COSV56566091; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGTR1 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 9/240 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs1246422058; called by muse, mutect2
- ANKRD20A2P | c.202A>G p.R68G | Missense Mutation (SNP) | VAF 47/946 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs1351892458; called by muse, mutect2
- B3GNTL1 | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.463); catalogued as COSV100301988; called by muse, mutect2
- BEST1 | c.431G>A p.S144N | Missense Mutation (SNP) | VAF 81/468 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CM100162, COSV57120548; called by muse, mutect2, varscan2
- BTK | c.914T>A p.I305N | Missense Mutation (SNP) | VAF 69/283 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as CM0911428; called by muse, mutect2, varscan2
- CACNA1C | c.4943C>T p.A1648V | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs767199033, COSV59744875; called by muse, mutect2, varscan2
- CAPN15 | c.1769A>G p.D590G | Missense Mutation (SNP) | VAF 25/679 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54835489; called by muse, mutect2
- CCDC154 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 23/364 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs1194249666; called by muse, mutect2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 22/155 reads (14%) | catalogued as rs751135235; called by mutect2, varscan2
- CDH22 | c.964A>G p.S322G | Missense Mutation (SNP) | VAF 59/543 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs774356645, COSV64836824; called by muse, mutect2, varscan2
- CDH24 | c.256del p.E86Rfs*8 | Frame Shift Del (DEL) | VAF 19/181 reads (10%) | catalogued as rs770812492; called by mutect2, pindel, varscan2
- CIC | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 11/285 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.301); catalogued as rs1408364216; called by muse, mutect2
- CLNK | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1212327203; called by muse, mutect2
- COL5A1 | c.5498C>T p.P1833L | Missense Mutation (SNP) | VAF 78/571 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as rs759733869; called by muse, mutect2, varscan2
- DCHS1 | c.6518G>A p.R2173Q | Missense Mutation (SNP) | VAF 72/540 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV55032676; called by muse, mutect2, varscan2
- DMXL1 | c.4018C>T p.R1340W | Missense Mutation (SNP) | VAF 46/360 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs993973809, COSV60703916, COSV60705722; called by muse, mutect2, varscan2
- DOHH | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 110/948 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51744795; called by muse, varscan2
- DOK7 | c.278G>A p.S93N | Missense Mutation (SNP) | VAF 40/256 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1225681847, COSV60773395; called by muse, mutect2, varscan2
- EDEM1 | c.196del p.V66Yfs*108 | Frame Shift Del (DEL) | VAF 21/158 reads (13%) | catalogued as rs753811182; called by mutect2, pindel, varscan2
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 16/154 reads (10%) | catalogued as rs770453803; called by mutect2, varscan2
- ESCO1 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 62/359 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1331453833; called by muse, mutect2, varscan2
- FANCE | c.681_683del p.E227del | In Frame Del (DEL) | VAF 113/992 reads (11%) | catalogued as rs777249237; called by pindel, varscan2
- FAXC | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 60/469 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs748805535, COSV67602086; called by muse, mutect2, varscan2
- FKBP6 | c.448A>G p.K150E | Missense Mutation (SNP) | VAF 89/724 reads (12%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as rs1199831840; called by muse, mutect2, varscan2
- GORASP2 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs761792319; called by muse, mutect2, varscan2
- HCN4 | c.3439G>A p.G1147S | Missense Mutation (SNP) | VAF 65/474 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.029); catalogued as rs747427482; called by muse, mutect2, varscan2
- HOOK2 | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 58/409 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV99317267; called by muse, mutect2, varscan2
- ITIH5 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 70/501 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.157); catalogued as rs747244720, COSV56898161; called by muse, mutect2, varscan2
- JAM2 | c.855G>A p.M285I | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as rs1280939312, COSV100468313; called by muse, mutect2
- KNL1 | c.4211A>G p.Q1404R (on ENST00000346991 / NM_170589.5; = p.Q1378R on NM_144508.5) | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.425); catalogued as rs776081369; called by muse, mutect2, varscan2
- KRT17 | c.65del p.G22Afs*93 | Frame Shift Del (DEL) | VAF 68/515 reads (13%) | catalogued as rs753167272; called by mutect2, pindel, varscan2
- LCE3E | c.128del p.G43Afs*12 | Frame Shift Del (DEL) | VAF 72/632 reads (11%) | catalogued as COSV64231527; called by mutect2, varscan2
- LRRC7 | c.4359G>T p.Q1453H (on ENST00000651989 / NM_001370785.2; = p.Q1373H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/545 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV99224388; called by muse, mutect2, varscan2
- MBOAT1 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.575); catalogued as rs765668536; called by muse, mutect2, varscan2
- MCMDC2 | c.1193G>A p.G398D | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as rs141240294; called by muse, mutect2, varscan2
- MICB | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.877); catalogued as rs757078199, COSV52857218; called by muse, mutect2
- MOV10 | c.2599_2601del p.E867del | In Frame Del (DEL) | VAF 30/214 reads (14%) | catalogued as rs1557774126; called by pindel, varscan2
- MPND | c.1343G>A p.S448N | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.526); catalogued as rs1349729589; called by muse, mutect2, varscan2
- MYO9B | c.3005C>T p.T1002M | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.076); catalogued as rs1237355706; called by muse, mutect2
- NALCN | c.5011C>T p.R1671C | Missense Mutation (SNP) | VAF 63/524 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as rs143587652; called by muse, mutect2, varscan2
- NALCN | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 19/429 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.229); catalogued as COSV51919955, COSV51934768; called by muse, mutect2
- NANOGNB | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 48/286 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.602); catalogued as rs866678269, COSV66125067; called by muse, mutect2, varscan2
- NDST4 | c.970G>T p.D324Y | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52108656; called by muse, mutect2
- NELFA | c.1597A>C p.K533Q (on ENST00000542778; = p.K522Q on NM_005663.5) | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs929528469, COSV100374111; called by muse, mutect2, varscan2
- NFATC4 | c.2660G>A p.R887Q | Missense Mutation (SNP) | VAF 59/284 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as rs758997767, COSV99147010; called by muse, mutect2, varscan2
- NMNAT2 | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.185); catalogued as rs1229874213; called by muse, mutect2, varscan2
- NMUR1 | c.245G>A p.C82Y | Missense Mutation (SNP) | VAF 60/464 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1385828552, COSV59403766; called by muse, mutect2, varscan2
- OR4C15 | c.63G>A p.M21I | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs780050162; called by muse, mutect2
- OR51M1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 13/329 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as COSV60785387; called by muse, mutect2
- P2RY8 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 70/543 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.757); catalogued as COSV101183954; called by muse, mutect2, varscan2
- PCDH8 | c.2675del p.P892Lfs*45 | Frame Shift Del (DEL) | VAF 69/556 reads (12%) | catalogued as COSV100132086, COSV58813340; called by mutect2, pindel, varscan2
- PCDHA4 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 17/538 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as COSV100793461; called by muse, mutect2
- PCDHGA11 | c.1910A>G p.D637G | Missense Mutation (SNP) | VAF 26/385 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53915477; called by muse, mutect2
- PCSK4 | c.1933G>A p.A645T | Missense Mutation (SNP) | VAF 61/524 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1410862797; called by muse, mutect2, varscan2
- PDLIM4 | c.669C>T p.G223= | Splice Region (SNP) | VAF 22/485 reads (5%) | catalogued as COSV53805279; called by muse, mutect2
- PLXNA1 | c.4694G>A p.R1565H | Missense Mutation (SNP) | VAF 51/362 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs142147514, COSV52530883; called by muse, mutect2, varscan2
- POLE | c.6073G>A p.V2025M | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as rs995579204, COSV57684467; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPIP5K2 | c.1279C>A p.P427T | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58605632; called by muse, mutect2
- PRPF4 | c.1372+1G>A p.X458_splice (on ENST00000374198 / NM_001322267.2; = p.X459_splice on NM_004697.5) | Splice Site (SNP) | VAF 26/261 reads (10%) | catalogued as rs1443418385, COSV65252536; called by muse, mutect2, varscan2
- PSD4 | c.2401C>T p.R801C | Missense Mutation (SNP) | VAF 68/506 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1313226455; called by muse, mutect2, varscan2
- RAB11FIP4 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 40/361 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs950815562; called by muse, mutect2, varscan2
- RAD52 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs749036119; called by muse, mutect2, varscan2
- RASSF9 | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV63433605; called by muse, mutect2
- RNF13 | c.829del p.T277Pfs*29 | Frame Shift Del (DEL) | VAF 14/139 reads (10%) | catalogued as rs1559980566; called by mutect2, pindel
- RSF1 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.813); catalogued as rs865783320; called by muse, mutect2
- RTP2 | c.473G>A p.C158Y | Missense Mutation (SNP) | VAF 40/301 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100832850, COSV100832936; called by muse, mutect2, varscan2
- RYR2 | c.5570C>T p.P1857L | Missense Mutation (SNP) | VAF 39/301 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs568198475, COSV63668649; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SECISBP2L | c.715A>G p.M239V | Missense Mutation (SNP) | VAF 40/278 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs765230609; called by muse, mutect2, varscan2
- SIGLEC1 | c.3037G>A p.A1013T | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as rs1190381533, COSV52470212; called by muse, mutect2
- SIRT6 | c.80del p.P27Rfs*133 | Frame Shift Del (DEL) | VAF 17/145 reads (12%) | catalogued as rs766524945, COSV59446625; called by mutect2, varscan2
- SLC35G1 | c.488C>T p.T163M (on ENST00000427197 / NM_001134658.3; = p.T162M on NM_153226.4) | Missense Mutation (SNP) | VAF 53/391 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.109); catalogued as rs1391420155, COSV65055405; called by muse, mutect2, varscan2
- SMCHD1 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 15/364 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1555632935; ClinVar: uncertain significance; called by muse, mutect2
- SPHK2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 24/383 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs201848542; called by muse, mutect2
- SPPL3 | c.102-1G>T p.X34_splice | Splice Site (SNP) | VAF 11/250 reads (4%) | catalogued as COSV62231254; called by muse, mutect2
- SSBP1 | c.431C>T p.T144M | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs553258138, COSV54680922; called by muse, mutect2
- TEAD1 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 84/696 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.156); catalogued as rs766021095; called by muse, mutect2, varscan2
- THBS3 | c.2803C>T p.R935* | Nonsense Mutation (SNP) | VAF 30/254 reads (12%) | catalogued as COSV100104335; called by muse, mutect2, varscan2
- TIGIT | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 11/306 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs977245811, COSV67329028; called by muse, mutect2
- TMEM104 | c.604del p.L202Cfs*35 | Frame Shift Del (DEL) | VAF 40/322 reads (12%) | catalogued as COSV100120745; called by mutect2, pindel, varscan2
- TNRC18 | c.1573G>A p.V525M | Missense Mutation (SNP) | VAF 105/781 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs746829993, COSV101259523; called by muse, mutect2, varscan2
- TOPORS | c.2261del p.N754Ifs*34 | Frame Shift Del (DEL) | VAF 41/212 reads (19%) | catalogued as rs755861530; called by mutect2, varscan2
- TPST1 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as COSV59178650; called by muse, mutect2
- TTPAL | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as rs374286934; called by muse, mutect2
- VWA7 | c.723G>A p.G241= | Splice Region (SNP) | VAF 10/101 reads (10%) | catalogued as COSV65155375; called by muse, mutect2
- WHRN | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 44/351 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1279323599; called by muse, mutect2, varscan2
- ZC3H4 | c.1376A>G p.N459S | Missense Mutation (SNP) | VAF 44/392 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as rs777076701, COSV53415541; called by muse, mutect2, varscan2
- ZDHHC13 | c.174-1G>T p.X58_splice | Splice Site (SNP) | VAF 20/133 reads (15%) | catalogued as rs1292995837; called by muse, mutect2
- ZFHX3 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 10/73 reads (14%) | catalogued as COSV51724051; called by muse, mutect2
- ZNF292 | c.6145del p.S2049Vfs*11 | Frame Shift Del (DEL) | VAF 37/254 reads (15%) | catalogued as rs764995318; called by mutect2, varscan2
- ZNF407 | c.4138A>G p.I1380V | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55249538; called by muse, mutect2, varscan2
- ZNF70 | c.242dup p.G82Rfs*7 | Frame Shift Ins (INS) | VAF 47/351 reads (13%) | catalogued as rs775749922; called by mutect2, pindel, varscan2
- ZNF865 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.22); catalogued as rs1188216751; called by muse, mutect2, varscan2
- ABCB5 | c.3337T>C p.Y1113H (on ENST00000404938 / NM_001163941.2; = p.Y668H on NM_178559.6) | Missense Mutation (SNP) | VAF 22/648 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCG8 | c.1514G>C p.C505S | Missense Mutation (SNP) | VAF 60/543 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ABHD17A | c.887G>A p.R296H (on ENST00000292577 / NM_001130111.2; = p.R347H on NM_031213.4) | Missense Mutation (SNP) | VAF 27/719 reads (4%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.996); called by muse, mutect2
- AC136428.1 | c.220A>C p.S74R | Missense Mutation (SNP) | VAF 34/784 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); called by muse, mutect2
- ADA | c.961_963del p.E321del | In Frame Del (DEL) | VAF 99/795 reads (12%) | called by pindel, varscan2
- AKAP11 | c.3656A>T p.D1219V | Missense Mutation (SNP) | VAF 9/251 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2
- ANTXR2 | c.689G>C p.C230S | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- APBB3 | c.246del p.R85Dfs*43 | Frame Shift Del (DEL) | VAF 73/500 reads (15%) | called by mutect2, varscan2
- BAP1 | c.226dup p.I76Nfs*4 | Frame Shift Ins (INS) | VAF 52/458 reads (11%) | called by mutect2, pindel, varscan2
- BCDIN3D | c.770G>A p.R257K | Missense Mutation (SNP) | VAF 46/433 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BIRC6 | c.5207del p.P1736Qfs*17 | Frame Shift Del (DEL) | VAF 19/131 reads (15%) | called by mutect2, pindel, varscan2
- C10orf82 | c.182C>G p.A61G | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- C12orf43 | c.680A>T p.N227I | Missense Mutation (SNP) | VAF 45/381 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- C1orf112 | c.312+2T>C p.X104_splice | Splice Site (SNP) | VAF 16/91 reads (18%) | called by muse, varscan2
- C2CD2 | c.1532G>T p.S511I | Missense Mutation (SNP) | VAF 82/596 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CBWD5 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 30/934 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2
- CDC5L | c.657G>T p.K219N | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CDHR4 | c.2084C>T p.T695I | Missense Mutation (SNP) | VAF 57/320 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CFAP58 | c.2138G>A p.W713* | Nonsense Mutation (SNP) | VAF 37/207 reads (18%) | called by muse, mutect2, varscan2
- COL4A3 | c.4972dup p.I1658Nfs*39 | Frame Shift Ins (INS) | VAF 46/381 reads (12%) | called by mutect2, pindel, varscan2
- COPB2 | c.2281T>C p.Y761H | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- COPZ1 | c.291_292del p.F98Rfs*29 | Frame Shift Del (DEL) | VAF 18/192 reads (9%) | called by pindel, varscan2
- CREG2 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 27/409 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.841); called by muse, mutect2
- CSMD2 | c.7128del p.Y2377Ifs*11 | Frame Shift Del (DEL) | VAF 45/463 reads (10%) | called by mutect2, pindel, varscan2
- CUBN | c.7991A>C p.Q2664P | Missense Mutation (SNP) | VAF 44/392 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- CYLC2 | c.490G>T p.G164C | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- CYP4F22 | c.1319T>C p.V440A | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- DCAF5 | c.690C>A p.N230K | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- DDC | c.1364T>C p.V455A | Missense Mutation (SNP) | VAF 36/875 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.013); called by muse, mutect2
- DLGAP4 | c.28del p.R10Afs*7 | Frame Shift Del (DEL) | VAF 17/128 reads (13%) | called by mutect2, pindel, varscan2
- DNAH11 | c.9925G>A p.V3309I | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- DPP10 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 11/227 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- DSP | c.3443G>A p.C1148Y | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2
- DST | c.4918A>G p.T1640A | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DTL | c.1624G>T p.E542* | Nonsense Mutation (SNP) | VAF 19/288 reads (7%) | called by muse, mutect2
- EIF2AK3 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 65/425 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- EIF2B5 | c.1621A>T p.M541L (on ENST00000647909; = p.M533L on NM_003907.3) | Missense Mutation (SNP) | VAF 43/495 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- EIF2B5 | c.1622T>A p.M541K (on ENST00000647909; = p.M533K on NM_003907.3) | Missense Mutation (SNP) | VAF 42/488 reads (9%) | SIFT tolerated (0.91); PolyPhen benign (0.062); called by muse, mutect2
- ENAM | c.2989A>G p.I997V | Missense Mutation (SNP) | VAF 89/559 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ESRP2 | c.287G>A p.S96N | Missense Mutation (SNP) | VAF 83/571 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBXO46 | c.1529T>C p.F510S | Missense Mutation (SNP) | VAF 17/488 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- FER1L5 | c.571T>C p.S191P | Missense Mutation (SNP) | VAF 25/589 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.212); called by muse, mutect2
- FLNC | c.5967G>T p.E1989D | Missense Mutation (SNP) | VAF 22/335 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.379); called by muse, mutect2
- FN1 | c.2207T>C p.F736S | Missense Mutation (SNP) | VAF 26/652 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FOXK1 | c.2007del p.K670Rfs*45 | Frame Shift Del (DEL) | VAF 62/650 reads (10%) | called by mutect2, pindel, varscan2
- FOXL3 | c.34T>G p.F12V | Missense Mutation (SNP) | VAF 16/494 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FXYD4 | c.212G>T p.S71I | Missense Mutation (SNP) | VAF 83/687 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- GART | c.2840C>T p.A947V | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2
- GLB1 | c.1353_1354insA p.Q452Tfs*5 | Frame Shift Ins (INS) | VAF 21/123 reads (17%) | called by mutect2, pindel
- GLI2 | c.3452A>G p.Q1151R (on ENST00000361492 / NM_001374353.1; = p.Q1168R on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/512 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2
- GPR141 | c.413G>C p.G138A | Missense Mutation (SNP) | VAF 9/225 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GPRASP1 | c.1805C>T p.T602I | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2
- GUF1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- H1-8 | c.657del p.K220Sfs*? | Frame Shift Del (DEL) | VAF 52/460 reads (11%) | called by mutect2, varscan2
- HACD1 | c.466A>G p.T156A | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- HACE1 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 30/599 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.274); called by muse, mutect2
- HIBADH | c.227_228del p.K76Rfs*7 | Frame Shift Del (DEL) | VAF 20/170 reads (12%) | called by mutect2, pindel
- HYLS1 | c.352T>A p.S118T | Missense Mutation (SNP) | VAF 52/868 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.012); called by muse, mutect2
- IL4I1 | c.1409C>T p.T470M | Missense Mutation (SNP) | VAF 59/426 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- ITGAV | c.2103G>T p.K701N | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNS2 | c.1308G>A p.M436I | Missense Mutation (SNP) | VAF 40/444 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- KCTD19 | c.2276T>C p.V759A | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- KIAA1958 | c.1276T>C p.Y426H | Missense Mutation (SNP) | VAF 45/314 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- KIF21B | c.2690A>G p.K897R | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KIF26B | c.5572C>T p.R1858W | Missense Mutation (SNP) | VAF 30/566 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2
- KLHL32 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 70/425 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- LIG4 | c.506del p.K169Rfs*7 | Frame Shift Del (DEL) | VAF 34/275 reads (12%) | called by mutect2, pindel, varscan2
- LRRC3 | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 46/360 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- LRRC31 | c.187A>T p.S63C | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- MAP2K5 | c.1333C>T p.Q445* (on ENST00000178640 / NM_145160.3; = p.Q435* on NM_002757.4) | Nonsense Mutation (SNP) | VAF 42/267 reads (16%) | called by muse, mutect2, varscan2
- MCTP1 | c.529del p.D177Tfs*66 | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | called by mutect2, pindel
- MFN2 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 141/1016 reads (14%) | called by muse, mutect2, varscan2
- MGAT4A | c.397dup p.T133Nfs*17 | Frame Shift Ins (INS) | VAF 23/212 reads (11%) | called by mutect2, pindel, varscan2
- MGLL | c.595dup p.L199Pfs*45 (on ENST00000398104 / NM_001003794.2; = p.L209Pfs*45 on NM_007283.6) | Frame Shift Ins (INS) | VAF 49/381 reads (13%) | called by mutect2, pindel, varscan2
- MLH1 | c.1228del p.A410Pfs*81 | Frame Shift Del (DEL) | VAF 89/440 reads (20%) | called by mutect2, pindel, varscan2
- MPDZ | c.1027G>T p.A343S | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2
- MTPAP | c.1491dup p.F498Ifs*25 | Frame Shift Ins (INS) | VAF 56/506 reads (11%) | called by mutect2, pindel, varscan2
- MYCBP2 | c.12415A>G p.K4139E (on ENST00000357337; = p.K4177E on NM_015057.5) | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- NEK4 | c.2050_2052del p.S684del | In Frame Del (DEL) | VAF 28/228 reads (12%) | called by pindel, varscan2
- NEMP1 | c.349del p.S117Pfs*4 | Frame Shift Del (DEL) | VAF 38/343 reads (11%) | called by mutect2, pindel, varscan2
- NFXL1 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- NOTCH3 | c.2476T>C p.C826R | Missense Mutation (SNP) | VAF 63/377 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPAS2 | c.2140A>C p.N714H | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.365); called by muse, mutect2
- NR6A1 | c.694T>C p.Y232H (on ENST00000487099 / NM_033334.4; = p.Y227H on NM_001489.5) | Missense Mutation (SNP) | VAF 38/356 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- PACS1 | c.1195_1199+1del | In Frame Del (DEL) | VAF 20/178 reads (11%) | called by mutect2, pindel, varscan2
- PARP12 | c.960G>T p.E320D | Missense Mutation (SNP) | VAF 29/261 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PAX1 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 40/1094 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.03); called by muse, mutect2
- PAX2 | c.1207del p.R403Gfs*37 (on ENST00000428433 / NM_003987.5; = p.R380Gfs*37 on NM_000278.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 50/533 reads (9%) | called by mutect2, pindel
- PIK3R1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, varscan2
- PIP5K1C | c.1874G>A p.S625N | Missense Mutation (SNP) | VAF 36/928 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.5); called by muse, mutect2
- PITPNM2 | c.3762G>T p.Q1254H | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PLS3 | c.151T>C p.Y51H | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- PRR32 | c.565T>G p.S189A | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- RALGAPA2 | c.1757_1760del p.I586Rfs*18 | Frame Shift Del (DEL) | VAF 30/291 reads (10%) | called by mutect2, pindel, varscan2
- RAP2C | c.70del p.V24Sfs*44 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- RAPGEF4 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 20/265 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2
- RFX5 | c.17C>A p.P6H | Missense Mutation (SNP) | VAF 41/308 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RGS22 | c.124dup p.S42Ffs*5 | Frame Shift Ins (INS) | VAF 16/143 reads (11%) | called by mutect2, pindel, varscan2
- RHOA | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- RIMS1 | c.4697del p.K1566Sfs*23 | Frame Shift Del (DEL) | VAF 25/165 reads (15%) | called by mutect2, pindel
- RINT1 | c.1242T>A p.S414R | Missense Mutation (SNP) | VAF 115/517 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- RRH | c.200T>G p.L67R | Missense Mutation (SNP) | VAF 11/353 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SETD2 | c.5808del p.C1936* | Frame Shift Del (DEL) | VAF 56/363 reads (15%) | called by mutect2, pindel, varscan2
- SLC6A7 | c.865A>G p.I289V | Missense Mutation (SNP) | VAF 8/197 reads (4%) | SIFT tolerated (0.91); PolyPhen benign (0.007); called by muse, mutect2
- SLC8A1 | c.808A>G p.K270E | Missense Mutation (SNP) | VAF 25/500 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); called by muse, mutect2
- SMARCAD1 | c.1685G>T p.R562M | Missense Mutation (SNP) | VAF 46/384 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SMC3 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 58/504 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- SMCR8 | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 68/635 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- SNX30 | c.556dup p.R186Kfs*12 | Frame Shift Ins (INS) | VAF 24/235 reads (10%) | called by mutect2, pindel, varscan2
- SPDYE1 | c.374A>C p.E125A | Missense Mutation (SNP) | VAF 32/1372 reads (2%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.874); called by muse, mutect2
- SRD5A1 | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- TBP | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 111/790 reads (14%) | called by muse, mutect2, varscan2
- TCF12 | c.1114+1G>A p.X372_splice | Splice Site (SNP) | VAF 12/280 reads (4%) | called by muse, mutect2
- TMEM232 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- TNFRSF14 | c.88C>A p.L30M | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- TNPO1 | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 21/556 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2
- TOR1AIP2 | c.394T>G p.L132V | Missense Mutation (SNP) | VAF 12/293 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.087); called by muse, mutect2
- TSPAN13 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.636); called by muse, mutect2
- TTN | c.18853C>T p.P6285S (on ENST00000591111; = p.P5358S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/122 reads (8%) | PolyPhen probably damaging (0.996); called by muse, mutect2
- TYW3 | c.426+2T>C p.X142_splice | Splice Site (SNP) | VAF 9/264 reads (3%) | called by muse, mutect2
- UBA6 | c.1876A>G p.T626A | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UBE4B | c.2130del p.Y710* (on ENST00000343090 / NM_001105562.3; = p.Y581* on NM_006048.5) | Frame Shift Del (DEL) | VAF 45/348 reads (13%) | called by mutect2, pindel, varscan2
- UBR1 | c.5077G>T p.D1693Y | Missense Mutation (SNP) | VAF 32/552 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- UBR4 | c.14282G>T p.G4761V | Missense Mutation (SNP) | VAF 24/666 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- USP34 | c.1167A>C p.K389N | Missense Mutation (SNP) | VAF 13/338 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- USP9Y | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 30/507 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.326); called by muse, mutect2
- UTRN | c.3643C>G p.Q1215E | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); called by muse, varscan2
- VPS13D | c.2894A>G p.Q965R | Missense Mutation (SNP) | VAF 24/510 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); called by muse, mutect2
- VPS50 | c.1337T>C p.V446A | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- WDR45 | c.641G>T p.G214V (on ENST00000376372 / NM_001029896.2; = p.G215V on NM_007075.3) | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZFHX3 | c.218A>C p.E73A | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.644); called by muse, mutect2
- ZNF121 | c.301T>C p.S101P | Missense Mutation (SNP) | VAF 23/513 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); called by muse, mutect2
- ZNF175 | c.1690T>C p.C564R | Missense Mutation (SNP) | VAF 11/269 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF217 | c.2033C>G p.P678R | Missense Mutation (SNP) | VAF 44/472 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.088); called by muse, mutect2
- ZNF407 | c.494A>C p.E165A | Missense Mutation (SNP) | VAF 18/434 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- ZNF507 | c.161T>C p.I54T | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ZNF516 | c.3111dup p.V1038Rfs*15 | Frame Shift Ins (INS) | VAF 43/373 reads (12%) | called by mutect2, pindel, varscan2
- ZNF787 | c.1021G>A p.V341M | Missense Mutation (SNP) | VAF 33/500 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); called by muse, mutect2
- AHI1 | c.3096T>C p.G1032= | Silent (SNP) | VAF 22/394 reads (6%) | called by muse, mutect2
- ALDH16A1 | c.2241A>C p.S747= | Silent (SNP) | VAF 12/216 reads (6%) | called by muse, mutect2
- AP2B1 | c.561C>A p.I187= | Silent (SNP) | VAF 49/438 reads (11%) | catalogued as COSV99250813; called by muse, mutect2, varscan2
- AP3B2 | c.3030C>T p.T1010= (on ENST00000261722; = p.T1004= on NM_004644.5) | Silent (SNP) | VAF 9/246 reads (4%) | called by muse, mutect2
- AP4E1 | c.1938C>A p.R646= | Silent (SNP) | VAF 46/533 reads (9%) | catalogued as rs760668736; called by muse, mutect2
- ARFGEF3 | c.2937G>A p.K979= | Silent (SNP) | VAF 57/502 reads (11%) | called by muse, mutect2, varscan2
- ARHGEF5 | c.666G>A p.L222= | Silent (SNP) | VAF 110/1944 reads (6%) | catalogued as rs771773626; called by muse, mutect2
- BAHCC1 | c.1053C>T p.A351= | Silent (SNP) | VAF 39/268 reads (15%) | catalogued as rs564931328; called by muse, mutect2, varscan2
- BCAT2 | c.594T>C p.G198= | Silent (SNP) | VAF 67/475 reads (14%) | catalogued as rs1312896705; called by muse, mutect2, varscan2
- BPIFB2 | c.222C>T p.V74= | Silent (SNP) | VAF 39/305 reads (13%) | called by muse, mutect2, varscan2
- CCDC116 | c.42C>T p.D14= | Silent (SNP) | VAF 32/259 reads (12%) | catalogued as rs1443297840; called by muse, mutect2, varscan2
- CCDC62 | c.1188A>G p.S396= | Silent (SNP) | VAF 26/172 reads (15%) | catalogued as rs1446077038; called by muse, mutect2, varscan2
- CEP350 | c.798T>C p.N266= | Silent (SNP) | VAF 74/372 reads (20%) | called by muse, mutect2, varscan2
- CMTR2 | c.579T>A p.I193= | Silent (SNP) | VAF 22/137 reads (16%) | called by muse, mutect2, varscan2
- CNP | c.243G>A p.V81= | Silent (SNP) | VAF 46/398 reads (12%) | catalogued as rs1043767606; called by muse, mutect2, varscan2
- CXCR1 | c.207C>T p.V69= | Silent (SNP) | VAF 69/360 reads (19%) | catalogued as rs761511554; called by muse, mutect2, varscan2
- DIDO1 | c.5649C>T p.G1883= | Silent (SNP) | VAF 17/318 reads (5%) | catalogued as COSV56621766; called by muse, mutect2
- DSG2 | c.1551A>G p.A517= | Silent (SNP) | VAF 77/577 reads (13%) | called by muse, mutect2, varscan2
- EFNA2 | c.18C>T p.R6= | Silent (SNP) | VAF 17/145 reads (12%) | catalogued as rs1016558380; called by muse, mutect2, varscan2
- EN2 | c.759C>T p.A253= | Silent (SNP) | VAF 66/555 reads (12%) | catalogued as rs753930381, COSV52083163; called by muse, mutect2, varscan2
- FUT11 | c.849C>T p.A283= | Silent (SNP) | VAF 40/375 reads (11%) | catalogued as rs1042344567; called by muse, mutect2, varscan2
- GAS6 | c.558C>T p.F186= | Silent (SNP) | VAF 60/415 reads (14%) | catalogued as rs781510990; called by muse, mutect2, varscan2
- GIMAP6 | c.357C>T p.S119= | Silent (SNP) | VAF 40/245 reads (16%) | catalogued as rs753596703, COSV61033577; called by muse, mutect2, varscan2
- GLUD2 | c.249C>T p.D83= | Silent (SNP) | VAF 57/559 reads (10%) | called by muse, mutect2
- GNB1L | c.582C>T p.D194= | Silent (SNP) | VAF 80/559 reads (14%) | catalogued as rs753000516, COSV100284475; called by muse, mutect2, varscan2
- H2BC18 | c.213C>T p.F71= | Silent (SNP) | VAF 92/890 reads (10%) | catalogued as rs1553754571, COSV100516198; called by muse, mutect2, varscan2
- HAPLN3 | c.639C>T p.N213= | Silent (SNP) | VAF 46/348 reads (13%) | catalogued as rs778766539, COSV61370418; called by muse, mutect2, varscan2
- HMCN1 | c.14310C>T p.S4770= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs748810127; called by muse, mutect2, varscan2
- HS1BP3 | c.556C>T p.L186= | Silent (SNP) | VAF 65/469 reads (14%) | called by muse, mutect2, varscan2
- ITGB8 | c.1758T>G p.P586= | Silent (SNP) | VAF 38/948 reads (4%) | called by muse, mutect2
- KIAA1109 | c.33T>A p.P11= | Silent (SNP) | VAF 21/137 reads (15%) | called by muse, mutect2, varscan2
- KMT2C | c.5352A>G p.Q1784= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs766731536; called by muse, mutect2
- LRCH1 | c.288C>A p.L96= | Silent (SNP) | VAF 31/772 reads (4%) | called by muse, mutect2
- LRP8 | c.795C>T p.F265= | Silent (SNP) | VAF 15/248 reads (6%) | called by muse, mutect2
- MLH3 | c.3723C>T p.Y1241= (on ENST00000355774 / NM_001040108.2; = p.Y1217= on NM_014381.3) | Silent (SNP) | VAF 62/485 reads (13%) | catalogued as rs145627040; called by muse, mutect2, varscan2
- MOCS1 | c.381A>C p.G127= | Silent (SNP) | VAF 62/517 reads (12%) | called by muse, mutect2, varscan2
- MROH5 | c.1665A>G p.L555= | Silent (SNP) | VAF 10/226 reads (4%) | called by muse, mutect2
- MSI1 | c.468G>A p.T156= | Silent (SNP) | VAF 24/203 reads (12%) | catalogued as rs555470172, COSV57456588; called by muse, mutect2, varscan2
- OBSL1 | c.2223A>G p.S741= | Silent (SNP) | VAF 64/400 reads (16%) | called by muse, mutect2, varscan2
- OR4C5 | c.93G>A p.T31= | Silent (SNP) | VAF 71/448 reads (16%) | catalogued as rs1408422247; called by muse, mutect2, varscan2
- OR51F1 | c.273A>G p.L91= | Silent (SNP) | VAF 15/291 reads (5%) | called by muse, mutect2
- OVOL1 | c.552G>A p.T184= | Silent (SNP) | VAF 38/321 reads (12%) | catalogued as COSV60120567; called by muse, mutect2, varscan2
- PAX8 | c.1125A>G p.P375= | Silent (SNP) | VAF 47/340 reads (14%) | called by muse, mutect2, varscan2
- PCARE | c.1425G>A p.P475= | Silent (SNP) | VAF 83/612 reads (14%) | catalogued as rs755455124, COSV100527490; called by muse, mutect2, varscan2
- PCDHA10 | c.1611C>T p.R537= | Silent (SNP) | VAF 152/1064 reads (14%) | catalogued as COSV56542404; called by muse, mutect2, varscan2
- PPM1H | c.486G>A p.A162= | Silent (SNP) | VAF 12/200 reads (6%) | catalogued as rs1289565526, COSV99956768; called by muse, mutect2
- PPP2R5D | c.192G>A p.P64= | Silent (SNP) | VAF 38/344 reads (11%) | catalogued as rs765929202, COSV57839969, COSV57840151; called by muse, mutect2, varscan2
- PRICKLE3 | c.270G>A p.S90= | Silent (SNP) | VAF 30/342 reads (9%) | catalogued as COSV54294883; called by muse, mutect2
- PRKCZ | c.270C>T p.G90= | Silent (SNP) | VAF 15/160 reads (9%) | called by muse, mutect2, varscan2
- PRRC2B | c.1047G>A p.R349= | Silent (SNP) | VAF 20/298 reads (7%) | catalogued as COSV61944157; called by muse, mutect2
- RALGAPA2 | c.1890C>T p.L630= | Silent (SNP) | VAF 26/620 reads (4%) | called by muse, mutect2
- RBM15B | c.1779G>A p.R593= | Silent (SNP) | VAF 7/157 reads (4%) | catalogued as rs1286097861; called by muse, mutect2
- RBMXL3 | c.735G>A p.P245= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as rs782396163; called by muse, mutect2, varscan2
- RGPD2 | c.21C>T p.Y7= | Silent (SNP) | VAF 95/766 reads (12%) | catalogued as rs772354573; called by muse, varscan2
- RGS7 | c.585G>A p.A195= | Silent (SNP) | VAF 96/714 reads (13%) | catalogued as rs747717735; called by muse, mutect2, varscan2
- SARDH | c.606C>A p.T202= | Silent (SNP) | VAF 72/487 reads (15%) | called by muse, mutect2, varscan2
- SKOR2 | c.2502C>T p.P834= | Silent (SNP) | VAF 9/223 reads (4%) | called by muse, mutect2
- SLC22A12 | c.1077C>A p.A359= | Silent (SNP) | VAF 42/279 reads (15%) | called by muse, mutect2, varscan2
- SLC35E4 | c.648C>T p.D216= | Silent (SNP) | VAF 30/179 reads (17%) | catalogued as rs1389885454; called by muse, mutect2
- SLC35G6 | c.393C>A p.A131= | Silent (SNP) | VAF 143/1156 reads (12%) | called by muse, mutect2, varscan2
- SLCO1A2 | c.637T>C p.L213= | Silent (SNP) | VAF 27/202 reads (13%) | called by muse, mutect2, varscan2
- SNRNP200 | c.5751T>C p.S1917= | Silent (SNP) | VAF 16/460 reads (3%) | called by muse, mutect2
- SUGP2 | c.810A>G p.Q270= | Silent (SNP) | VAF 14/340 reads (4%) | called by muse, mutect2
- SVIL | c.363G>A p.G121= | Silent (SNP) | VAF 16/332 reads (5%) | catalogued as COSV63443320; called by muse, mutect2
- TMEM117 | c.1455G>A p.S485= | Silent (SNP) | VAF 19/383 reads (5%) | catalogued as COSV56915247; called by muse, mutect2
- USF3 | c.5778T>C p.T1926= | Silent (SNP) | VAF 25/351 reads (7%) | called by muse, mutect2
- ZFP36L1 | c.726C>A p.T242= | Silent (SNP) | VAF 63/397 reads (16%) | catalogued as COSV60545797; called by muse, mutect2, varscan2
- ZNF107 | c.600C>T p.A200= | Silent (SNP) | VAF 14/200 reads (7%) | catalogued as rs773810648; called by muse, mutect2
- ZNF30 | c.189C>T p.I63= | Silent (SNP) | VAF 15/230 reads (7%) | catalogued as rs770348565, COSV100340535; called by muse, mutect2
- ZNF41 | c.1557G>A p.G519= | Silent (SNP) | VAF 56/225 reads (25%) | called by muse, mutect2, varscan2
- ZNF425 | c.1440G>A p.T480= | Silent (SNP) | VAF 8/111 reads (7%) | called by muse, mutect2
- ZNF444 | c.900C>T p.H300= | Silent (SNP) | VAF 56/519 reads (11%) | catalogued as rs1238412314; called by muse, mutect2, varscan2
- ZNF556 | c.1002G>A p.A334= | Silent (SNP) | VAF 78/506 reads (15%) | catalogued as rs373920533; called by muse, mutect2, varscan2
- ZNF699 | c.615G>T p.V205= | Silent (SNP) | VAF 12/331 reads (4%) | called by muse, mutect2
- ACSF3 | c.*445C>T | 3'UTR (SNP) | VAF 54/338 reads (16%) | called by muse, mutect2, varscan2
- ACSL3 | c.806-314C>T | Intron (SNP) | VAF 23/109 reads (21%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501555 G>A | 5'Flank (SNP) | VAF 11/145 reads (8%) | called by muse, mutect2
- ARHGAP22 | c.989-18C>T | Intron (SNP) | VAF 115/807 reads (14%) | catalogued as rs555116106; called by muse, mutect2, varscan2
- ATXN7 | c.500-11984C>A | Intron (SNP) | VAF 27/268 reads (10%) | called by muse, mutect2, varscan2
- BRAF | c.1862-24T>C | Intron (SNP) | VAF 26/281 reads (9%) | called by muse, mutect2
- C7orf50 | c.130-12792C>T | Intron (SNP) | VAF 54/331 reads (16%) | catalogued as rs746150558; called by muse, mutect2, varscan2
- C8G | c.*36C>T | 3'UTR (SNP) | VAF 51/394 reads (13%) | called by muse, mutect2, varscan2
- CCR6 | c.-28C>T | 5'UTR (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2, varscan2
- CDIPT | chr16:29865189 A>G | 5'Flank (SNP) | VAF 18/374 reads (5%) | catalogued as rs1047579497; called by muse, mutect2
- CHTF8 | chr16:69118487 G>A | 3'Flank (SNP) | VAF 78/624 reads (13%) | called by muse, mutect2, varscan2
- CLINT1 | c.1532-10C>T | Intron (SNP) | VAF 54/407 reads (13%) | catalogued as rs764544064; called by muse, mutect2, varscan2
- CLUAP1 | c.1092+57A>C | Intron (SNP) | VAF 44/294 reads (15%) | called by muse, mutect2, varscan2
- COL6A2 | c.*22G>T | 3'UTR (SNP) | VAF 34/297 reads (11%) | catalogued as rs1446806080; called by muse, mutect2, varscan2
- COL6A3 | c.6591+26del | Intron (DEL) | VAF 61/537 reads (11%) | catalogued as rs751914944; called by mutect2, pindel, varscan2
- CYFIP1 | c.1675-387C>T | Intron (SNP) | VAF 7/103 reads (7%) | catalogued as rs577046716; called by muse, mutect2
- DMD | c.*15A>G | 3'UTR (SNP) | VAF 36/248 reads (15%) | catalogued as rs149405184; ClinVar: likely benign; called by muse, mutect2, varscan2
- DOCK4 | c.5014-701_5014-700insT | Intron (INS) | VAF 14/62 reads (23%) | called by mutect2, pindel*, varscan2
- FAM86C1P | n.175del | RNA (DEL) | VAF 39/335 reads (12%) | catalogued as COSV60639774; called by mutect2, varscan2
- FOXN3 | c.-14-6724_-14-6723insCT | Intron (INS) | VAF 29/197 reads (15%) | called by mutect2, pindel, varscan2
- GLYCTK | c.*1248C>T | 3'UTR (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- GRK2 | c.555+11T>C | Intron (SNP) | VAF 38/305 reads (12%) | catalogued as rs1565066744; called by muse, mutect2, varscan2
- HMCN1 | c.-13G>A | 5'UTR (SNP) | VAF 30/272 reads (11%) | catalogued as COSV54879545, COSV54887017; called by muse, mutect2
- HMOX1 | c.736+11C>A | Intron (SNP) | VAF 90/671 reads (13%) | called by muse, mutect2, varscan2
- IZUMO4 | c.537-39G>A | Intron (SNP) | VAF 11/85 reads (13%) | catalogued as rs747002621; called by muse, mutect2, varscan2
- KIF5A | c.-14C>T | 5'UTR (SNP) | VAF 76/554 reads (14%) | called by muse, mutect2, varscan2
- KLHL29 | c.-45-29552C>T | Intron (SNP) | VAF 16/206 reads (8%) | called by muse, mutect2
- LIN28B | c.-67A>G | 5'UTR (SNP) | VAF 23/224 reads (10%) | called by muse, mutect2, varscan2
- LINC00615 | n.316G>A | RNA (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- MAPKBP1 | c.-1A>G | 5'UTR (SNP) | VAF 22/186 reads (12%) | called by muse, varscan2
- MIR548M | n.7G>C | RNA (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- NBPF11 | c.-549+2200C>T | Intron (SNP) | VAF 48/674 reads (7%) | catalogued as rs1461455778; called by muse, mutect2
- NDUFB9 | c.295-42del | Intron (DEL) | VAF 37/297 reads (12%) | called by mutect2, pindel, varscan2
- PIGN | c.1859+9A>G | Intron (SNP) | VAF 14/175 reads (8%) | called by muse, mutect2
- POM121L4P | n.1387C>T | RNA (SNP) | VAF 127/789 reads (16%) | catalogued as rs766662085; called by muse, mutect2, varscan2
- PRPF38B | c.558+385del | Intron (DEL) | VAF 18/124 reads (15%) | called by mutect2, varscan2
- PTPN6 | c.1674-118G>A | Intron (SNP) | VAF 54/265 reads (20%) | catalogued as rs370716043; called by muse, mutect2, varscan2
- QSOX1 | c.*1363C>T | 3'UTR (SNP) | VAF 26/180 reads (14%) | catalogued as rs984783361; called by muse, mutect2, varscan2
- RABL6 | c.-21C>T | 5'UTR (SNP) | VAF 47/594 reads (8%) | catalogued as rs1372016062; called by muse, mutect2
- RHBDL1 | chr16:675792 T>G | 5'Flank (SNP) | VAF 28/219 reads (13%) | called by muse, mutect2, varscan2
- RNF34 | c.6+2573del | Intron (DEL) | VAF 14/132 reads (11%) | called by mutect2, pindel, varscan2
- SART1 | c.372-37T>C | Intron (SNP) | VAF 12/362 reads (3%) | catalogued as rs1171454536; called by muse, mutect2
- SASH1 | c.730-5489C>T | Intron (SNP) | VAF 57/259 reads (22%) | catalogued as rs961104710; called by muse, mutect2, varscan2
- SFTPA1 | c.*922del | 3'UTR (DEL) | VAF 26/189 reads (14%) | catalogued as rs763121640; called by mutect2, varscan2
- SLC25A19 | c.775-43A>C | Intron (SNP) | VAF 30/236 reads (13%) | called by muse, mutect2, varscan2
- SPATA13 | c.*58C>A | 3'UTR (SNP) | VAF 18/172 reads (10%) | called by muse, mutect2
- SYNE3 | c.*8505C>T | 3'UTR (SNP) | VAF 33/466 reads (7%) | catalogued as rs557522891; called by muse, mutect2
- TMEM209 | chr7:130206937 G>T | 5'Flank (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2, varscan2
- TYW1 | c.-26C>A | 5'UTR (SNP) | VAF 22/426 reads (5%) | called by muse, mutect2
- UGT1A6 | c.862-12026C>T | Intron (SNP) | VAF 11/331 reads (3%) | called by muse, mutect2
- ZNF335 | c.-110del | 5'UTR (DEL) | VAF 33/301 reads (11%) | called by mutect2, pindel, varscan2
- ZNF565 | c.256+20C>T | Intron (SNP) | VAF 25/537 reads (5%) | catalogued as rs1247000174; called by muse, mutect2
- ZNF8 | c.66+646C>T | Intron (SNP) | VAF 57/331 reads (17%) | called by muse, mutect2, varscan2
- ZNF849P | n.1336G>A | RNA (SNP) | VAF 14/452 reads (3%) | catalogued as rs1439337849; called by muse, mutect2
- ZYG11B | c.1695+3380G>A | Intron (SNP) | VAF 20/115 reads (17%) | called by muse, mutect2, varscan2
